Surgical pathology report (de-identified scan), TCGA case TCGA-V3-A9ZY, project TCGA-UVM (Uveal Melanoma), tissue source site Cleveland Clinic Foundation, specimen TCGA-V3-A9ZY-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

De-Identified Specimen Code

Patient Age/Sex / M

SPECIMEN SUBMITTED:

RIGHT EYE ORBIT

ICD O-3

Melanoma, epithelioid
8771/3

Site @ Choroid
C69.3

As 5/19/14

Final Diagnosis

Right eye, enucleation - Malignant choroidal melanoma, predominantly epithelioid cell type.
- See synoptic report for summary of key pathologic findings.

Intraoperative Diagnosis:

{Not Entered}

Clinical Diagnosis:

190.6

Gross Description:

A. Received fresh labeled "right eye orbit" is a collapsed right eye measuring 23.95 mm superoinferior, 22.60 mm anteroposteriorly, and 23.90 mm horizontally. The globe is round in shape. A 2.96 mm length of optic nerve is present. The pupil is round and measures 7.26 mm in diameter. The cornea has been surgically removed from the globe. The sclera is smooth and glistening. On transillumination of the globe a shadow is identified. The globe is opened in a superior inferior meridian which best demonstrates the lesion which is located along the posterior aspect of the globe between 3:00 and 6:00. The mass is dark gray on cut surface and measures 7.79 mm in largest basal diameter, and 12.18 mm in height. The mass does involve the choroid and does not extend into the optic nerve. A photograph is taken of the globe after sectioning. The specimen is totally submitted as follows: A1 nasal calotte, A2 pupil optic nerve sectioned, A3 temporal calotte, A4 optic nerve shave margin.

Microscopic:

{Not Entered}

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Synoptic Data:

RIGHT EYE ORBIT:

Procedure:

Enucleation

Specimen Size:

For Enucleation

Anteroposterior diameter: 22.6 mm

Horizontal diameter: 23.9 mm

Vertical diameter: 24 mm

Length of optic nerve: 3 mm

For Enucleation-Diameter of optic nerve 3.5 mm (Slide measurement)

Specimen Laterality:

Right

Tumor Site (macroscopic examination/transillumination):

Inferonasal quadrant of globe

Tumor Location After Sectioning:

Distance from anterior edge of tumor to limbus at cut edge: 5 mm

Distance of posterior margin of tumor base from edge of optic disc: 4 mm

Tumor Involvement of Other Ocular Structures:

Sclera

Choroid

Histologic Type:

Epithelioid cell type

Histopathologic Type:

Epithelioid cell melanoma (greater than 90% epithelioid cells)

Histologic Grade (pG):

pG3: Epithelioid cell melanoma

Tumor Size After Sectioning:

Base at cut edge: 7.8 mm

Greatest height: 12.2 mm

Tumor Location:

Anterior margin between equator and iris

Posterior margin between disc and equator

Scleral Involvement:

Intrascleral

Margins:

No melanoma at margins

Growth Pattern:

Solid mass

TNM Descriptors:

Not applicable

Primary Tumor (pT):

Iris:

Not Applicable

Ciliary Body and Choroid:

pT3a: Tumor size category 3 without ciliary body involvement and extraocular extension

Regional Lymph Nodes (pN):

pNX: Regional lymph nodes cannot be assessed

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Synoptic Data:

Distant Metastasis (pM):

Not applicable

Additional Pathologic Findings:

Mitotic rate per 40 HPFs (Field Diameter=0.55mm): 3 mitotic figures per 40 high power fields (3/40) (Field Diameter=0.55mm)

Extravascular matrix pattern (PAS stain): Not identified

Degree of pigmentation:

mild

Macrophages:

few

Tumor infiltrating lymphocytes:

few

Retinal detachment

Invasion of Bruch's membrane

Other: Cataract

Source: NCI Genomic Data Commons file f27cabe0-ec5f-40b9-8cd3-c7abe4a4ba61 (TCGA-V3-A9ZY.163AE028-0550-4AEF-89A3-83600276EE4B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).